Somatic mutation profile of tumor specimen MP2PRT-PARKPM-TMP1-A (aliquot MP2PRT-PARKPM-TMP1-A-1-0-D-A834-36) from MP2PRT case MP2PRT-PARKPM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.4 years (1,625 days).
Specimen MP2PRT-PARKPM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 140ccadf-64fe-4bf8-a9bd-a420801826a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARKPM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARKPM-NB1-A-1-0-D-A834-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67ad1704-0046-49d6-9f8a-9570c164251e

The open-access MAF lists 18 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 13, Silent 3, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP44 | c.1468C>T p.R490W | Missense Mutation (SNP) | VAF 54/641 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1341782042, COSV52401655; called by muse, mutect2
- DMD | c.1687C>T p.R563C | Missense Mutation (SNP) | VAF 158/509 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as rs145739725, COSV55897518; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- KLHL38 | c.265G>A p.V89I | Missense Mutation (SNP) | VAF 111/345 reads (32%) | SIFT tolerated (0.65); PolyPhen benign (0.012); catalogued as rs765090496, COSV58086134; called by muse, mutect2, varscan2
- LDLRAD4 | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 138/343 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as rs764341458, COSV63340176; called by muse, mutect2, varscan2
- NHSL1 | c.962A>G p.D321G | Missense Mutation (SNP) | VAF 16/603 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1208642440, COSV100606633; called by muse, mutect2
- PCSK7 | c.1322G>A p.R441Q | Missense Mutation (SNP) | VAF 112/350 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs746679024; called by muse, mutect2, varscan2
- PTPRS | c.4801G>A p.V1601I | Missense Mutation (SNP) | VAF 49/564 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs367918810; called by muse, mutect2
- SELE | c.1747C>T p.R583W | Missense Mutation (SNP) | VAF 100/273 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as rs779327316; called by muse, mutect2, varscan2
- TSC1 | c.2117G>A p.R706H | Missense Mutation (SNP) | VAF 215/630 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53764528; called by muse, mutect2, varscan2
- TSPAN4 | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 52/790 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.108); catalogued as rs371055480; called by muse, mutect2
- AFF2 | c.3516G>T p.K1172N | Missense Mutation (SNP) | VAF 72/483 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ITPK1 | c.896T>A p.F299Y | Missense Mutation (SNP) | VAF 48/642 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); called by muse, mutect2
- METTL18 | c.425_426dup p.G143Lfs*5 | Frame Shift Ins (INS) | VAF 118/372 reads (32%) | called by mutect2, pindel, varscan2
- SMARCA1 | c.1240A>T p.K414* | Nonsense Mutation (SNP) | VAF 49/241 reads (20%) | called by muse, mutect2, varscan2
- WWC3 | c.972G>C p.E324D | Missense Mutation (SNP) | VAF 21/882 reads (2%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); called by muse, mutect2
- MAGED2 | c.522C>G p.A174= | Silent (SNP) | VAF 114/674 reads (17%) | called by muse, mutect2, varscan2
- NAV2 | c.1920G>A p.A640= (on ENST00000396087 / NM_001244963.2; = p.A617= on NM_145117.5) | Silent (SNP) | VAF 250/667 reads (37%) | catalogued as rs531952049, COSV100586945; called by muse, mutect2, varscan2
- RTN2 | c.12C>T p.V4= | Silent (SNP) | VAF 59/914 reads (6%) | called by muse, mutect2
